Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZO, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZO-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Physician:

Collector:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, nos c73.9

fw
6/17/12

(A) CRICOID THYROID MUSCLE:

Atrophic muscle negative for tumor.

(B) TOTAL THYROIDECTOMY:

PAPILLARY THYROID CARCINOMA WITH FOCAL POORLY DIFFERENTIATED AREAS

Location: Right lobe

Multi-focal: No

Size = 2.4 cm

Extrathyroidal extension: Present, extending into skeletal muscle

Lymphovascular invasion: Present

Resection Margins: Close < 1 mm.

(C) RIGHT PARATHYROID INFERIOR:

Parathyroid tissue present.

(D) LATERAL PARATRACHEAL LYMPH NODE:

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF FOUR LYMPH NODES (1/4).

Extranodal extension is not identified.

(E) MEDIAL PARATRACHEAL DISSECTION:

Three lymph nodes, negative for tumor. (0/3).

GROSS DESCRIPTION

(A) CRICOID THYROID MUSCLE - Received is a single fragment of fibromuscular tissue measuring 0.7 x 0.4 x 0.3 cm. Entirely submitted for frozen section in cassette A.

*FS/DX: MUSCLE WITH FOCAL SCARRING AND ATROPHY, NO TUMOR IDENTIFIED.

(B) TOTAL THYROIDECTOMY - An asymmetric total thyroidectomy specimen with right lobe (4.5 x 2.4 x 2.0 cm), isthmus (1.5 x 1.8 x 0.4 cm) and left lobe (3.4 x 2.0 x 0.8 cm).

The right lobe is distended and nodular by a firm white irregular mass (2.0 x 2.4 x 1.8 cm) present in the right upper pole abutting soft tissue without thyroid parenchyma overlying the superior portion. The anterior surface of the right lobe is covered by a skeletal muscle (2.5 x 3.0 cm area). Background colloid nodules are identified within the right lobe, isthmus, and left lobes. No other mass lesions are identified.

SECTION CODE: B1, B2, left lobe of thyroid upper to inferior; B3, left inferior lobe; B4, isthmus; B5-B8, right upper lobe nodule; B9-B10, sections from right inferior lobe.

(C) RIGHT PARATHYROID INFERIOR - Received is a single dark red nodule for frozen section weighing 0.01 gram and measuring 0.3 x 0.2 x 0.1 cm. One touch prep of the nodule is prepared. The entire nodule is submitted for frozen section in cassette C.

Page 1 of 2

Surgical Pathology Report

File under: Pathology

[page 2 of 2]
Surgical Pathology Report

DOB:
Physician:

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

*FS/DX: PARATHYROID, WEIGHT 0.01 GRAM.

(D) LATERAL PARATRACHEAL LYMPH NODE – Received are several fragments of fatty tissue measuring in aggregate, 1.5 x 1.0 x 0.5 cm. Entirely submitted in cassette D.

(E) MEDIAL PARATRACHEAL DISSECTION – Received is a single fragment of a fatty tissue measuring 3.0 x 3.0 x 0.8 cm. Dissection reveals two possible lymph nodes ranging from 0.6 up to 0.7 cm in greatest dimension. The lymph nodes and rest of tissue are entirely submitted.

SECTION CODE: E1, one possible lymph node; E2, one sectioned possible lymph node; E3, E4, rest of soft tissue.

CLINICAL HISTORY

Thyroid cancer.

SNOMED CODES

T-B6000, M-80503, T-C4200, M-80506

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 2 of 2
File under: Pathology		

Source: NCI Genomic Data Commons file cd110fe2-6ed8-4976-98a2-e2dc98d9d924 (TCGA-EL-A3ZO.FF6B5F00-9DE1-4073-AC35-7B65378B73EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).